Gene-level copy-number profile of tumor specimen C3L-02504-01 from CPTAC case C3L-02504, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.9 years (26,277 days).
Specimen C3L-02504-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 691b926a-437a-48d3-a25f-2c463e702cd6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02504-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/76a019d9-5229-479a-9f0c-e37315398fbf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 42; copy number 2: 6,726; copy number 3: 414; copy number 4: 47,932; copy number 5: 653; copy number 6: 2,950; copy number 7: 72; copy number 8: 25; copy number 9: 3; copy number 12: 10; copy number 61: 41.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 20 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:24,542,952–26,644,595, 9 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1.
- chr9:42,183,659–42,204,988, 3 genes: SPATA31A6, AL445584.1, FAM74A7.
- chr9:64,486,164–64,489,786, 2 genes: CNN2P3, GXYLT1P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 54 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–54,446,723, 41 genes, copy number 61: AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1.
- chr4:56,710,060–56,977,606, 10 genes, copy number 12: RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1.
- chr22:18,773,665–18,843,399, 3 genes, copy number 9: GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
